Somatic mutation profile of tumor specimen MMRF_1629_1_BM_CD138pos (aliquot MMRF_1629_1_BM_CD138pos_T2_KBS5U_K11924) from MMRF case MMRF_1629, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,372 days).
Specimen MMRF_1629_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8713316-90d0-453e-a945-dd6eac99b6f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1629_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1629_1_PB_Whole_C7_KBS5U_K11892; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd862873-efa6-4c57-a7c2-fa35648fbf82

The open-access MAF lists 75 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 19, Silent 9, Intron 8, 5'Flank 4, Frame Shift Del 2, 5'UTR 2, Splice Region 2, 3'Flank 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*194G>A | 3'UTR (SNP) | VAF 28/77 reads (36%) | catalogued as rs28931614, CM940785, CM940786, CX090489, COSV53399372, COSV99602429; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ALK | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66566402; called by muse, mutect2
- GANAB | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs556345168; called by muse, mutect2, varscan2
- IGLV3-1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs189772470; called by muse, varscan2
- MUC5B | c.1090T>G p.F364V | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1357191763; called by muse, mutect2, varscan2
- P2RY2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs757688695, COSV60775977; called by muse, mutect2, varscan2
- PAPPA2 | c.5348G>A p.R1783Q | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs552985138, COSV62799303; called by muse, mutect2, varscan2
- PFAS | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as rs1367149278, COSV58983230; called by muse, mutect2, varscan2
- RYR1 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1274823763, COSV62092082, COSV62113411; called by muse, mutect2, varscan2
- SDSL | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747826836, COSV61885487; called by muse, mutect2, varscan2
- SF3B3 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV56784937, COSV56786546; called by muse, mutect2, varscan2
- XKR6 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs767011160; called by muse, mutect2, varscan2
- ADGRL3 | c.1946A>G p.N649S (on ENST00000506720 / NM_001322402.2; = p.N581S on NM_015236.6) | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C4A | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CELSR3 | c.4580T>A p.M1527K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- DCK | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- EN1 | c.371del p.P124Rfs*171 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- GLI2 | c.386A>T p.Y129F | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXB8 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ICAM5 | c.2496C>T p.A832= | Splice Region (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- KCNH7 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MUC16 | c.11578A>G p.T3860A | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- NFKBIE | c.1159G>A p.E387K (on ENST00000275015; = p.E248K on NM_004556.3) | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SEMA3C | c.1199T>G p.F400C | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG4 | c.179_186del p.P60Qfs*49 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- TAOK1 | c.2077A>T p.N693Y | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCTE1 | c.1498G>T p.V500L | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD1 | c.1554A>T p.R518= | Splice Region (SNP) | VAF 58/150 reads (39%) | called by muse, mutect2, varscan2
- TMIGD1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- TTC38 | c.738C>G p.D246E | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF18 | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF598 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ALPG | c.564C>T p.Y188= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- ASTN1 | c.1020C>T p.S340= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs138051324; called by muse, mutect2, varscan2
- GSS | c.220C>T p.L74= | Silent (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- KIAA0319 | c.1875A>C p.P625= | Silent (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- KIF14 | c.306G>A p.L102= | Silent (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- NFRKB | c.3126C>A p.V1042= (on ENST00000446488 / NM_001143835.2; = p.V1067= on NM_006165.3) | Silent (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- NID1 | c.2520G>A p.V840= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- PLOD2 | c.363T>C p.G121= | Silent (SNP) | VAF 98/161 reads (61%) | called by muse, mutect2, varscan2
- SPTB | c.5616G>A p.E1872= | Silent (SNP) | VAF 56/76 reads (74%) | catalogued as rs767825891; called by muse, mutect2, varscan2
- AKAP11 | c.*1003G>A | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- AP000281.2 | chr21:32852108 G>A | 5'Flank (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2
- ARL5B | c.*4493T>C | 3'UTR (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021251 G>A | 5'Flank (SNP) | VAF 49/110 reads (45%) | catalogued as rs544175880, COSV55846942, COSV55850498; called by muse, varscan2
- BCL7A | chr12:122021401 G>C | 5'Flank (SNP) | VAF 42/108 reads (39%) | catalogued as rs547304687, COSV55852870; called by muse, varscan2
- CHRNA4 | c.*415G>A | 3'UTR (SNP) | VAF 59/139 reads (42%) | catalogued as rs767558331; called by muse, mutect2, varscan2
- CNTN5 | c.*2415T>A | 3'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2
- CNTN5 | c.*2417A>T | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2
- CYRIA | c.*3029T>C | 3'UTR (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- DCC | c.3163+233A>G | Intron (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- DLX2 | c.-240C>A | 5'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- FAM9C | c.329+13G>A | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- GNA12 | c.526-29206C>T | Intron (SNP) | VAF 34/132 reads (26%) | catalogued as rs1017210445; called by muse, mutect2, varscan2
- GSKIP | c.*1164G>T | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.703-191T>C | Intron (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- KMT2A | c.*615C>G | 3'UTR (SNP) | VAF 38/111 reads (34%) | catalogued as rs782460416, COSV100244975; called by muse, mutect2, varscan2
- LINC02076 | n.529C>T | RNA (SNP) | VAF 61/349 reads (17%) | catalogued as rs765711918; called by muse, mutect2, varscan2
- LPP | c.*14927T>A | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- MAP9 | c.*1529C>G | 3'UTR (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- MYO1E | c.-18A>G | 5'UTR (SNP) | VAF 38/51 reads (75%) | called by muse, mutect2, varscan2
- NFIB | c.*6333T>G | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- PCNX2 | c.3837+207T>G | Intron (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- PECR | c.*767G>T | 3'UTR (SNP) | VAF 20/51 reads (39%) | catalogued as rs1423444047; called by muse, mutect2, varscan2
- POU6F2 | chr7:39465698 C>T | 3'Flank (SNP) | VAF 75/122 reads (61%) | catalogued as rs955553134; called by muse, mutect2
- PRKAA1 | c.*1902C>G | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- PSMD8 | c.360+105G>A | Intron (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- RAB3C | c.*6032G>A | 3'UTR (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-4020G>A | Intron (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- SHCBP1 | chr16:46624156 C>T | 5'Flank (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- SPAG9 | c.*2703G>A | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- TAF8 | c.*4452A>G | 3'UTR (SNP) | VAF 14/52 reads (27%) | catalogued as rs559150877, COSV65897232; called by muse, mutect2, varscan2
- TDRP | c.*1455C>T | 3'UTR (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- UFM1 | c.190+410A>G | Intron (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- ZNF813 | c.*696A>T | 3'UTR (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
